Somatic mutation profile of tumor specimen TCGA-78-7153-01A (aliquot TCGA-78-7153-01A-11D-2036-08) from TCGA case TCGA-78-7153, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.5 years (23,922 days).
Specimen TCGA-78-7153-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca1bf9e3-97e1-4875-91a5-49c7dbff8e17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7153-10A (Blood Derived Normal), aliquot TCGA-78-7153-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0df48670-c857-469e-b1fa-c06ca744fc5a

The open-access MAF lists 111 somatic variants for this specimen: 88 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 74, Silent 23, Frame Shift Del 4, Splice Site 4, Nonsense Mutation 4, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>C p.G506A (on ENST00000288602 / NM_001374244.1; = p.G466A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.97T>A p.S33T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1057519886, COSV62688086, COSV62689225, COSV62704131; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAL | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs1369513169, COSV67500333; called by muse, mutect2, varscan2
- ADAM33 | c.1849C>A p.L617M | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as COSV62937206; called by muse, mutect2, varscan2
- ARSD | c.760T>A p.W254R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54203544; called by muse, mutect2, varscan2
- CCDC69 | c.437C>A p.A146D | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs1215250065, COSV62600918; called by muse, mutect2
- CCSER1 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as COSV61475637; called by muse, mutect2, varscan2
- CFAP54 | c.6607A>G p.N2203D | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.421); catalogued as COSV61575962; called by muse, mutect2, varscan2
- CUL9 | c.3919C>T p.R1307W | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs374291463, COSV52725461; called by muse, mutect2, varscan2
- DAGLA | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV57200702; called by muse, mutect2
- DEFB106B | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100128979; called by muse, mutect2, varscan2
- DMD | c.8669-1G>A p.X2890_splice | Splice Site (SNP) | VAF 10/82 reads (12%) | catalogued as CS103864, COSV58956347, COSV58958711; called by muse, mutect2, varscan2
- DNER | c.445G>C p.A149P | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.368); catalogued as COSV59178436; called by muse, mutect2
- EIF3D | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.597); catalogued as rs1004185481, COSV53405747; called by muse, mutect2, varscan2
- EXD1 | c.1047G>C p.E349D | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.11); catalogued as COSV59256869; called by muse, mutect2, varscan2
- EXTL3 | c.2464C>T p.R822W | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1464570972, COSV55040869; called by muse, mutect2, varscan2
- FAM135B | c.2819C>T p.T940M | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs200201819, COSV52708278, COSV99421433; called by muse, mutect2
- FAM204A | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV64988082; called by muse, mutect2
- FAM47A | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.344); catalogued as rs750698635, COSV60496289; called by muse, mutect2, varscan2
- FAM91A1 | c.580G>C p.D194H | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58240261; called by muse, mutect2
- FMR1 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.505); catalogued as COSV54423597, COSV54427999; called by muse, mutect2
- FOXN4 | c.1144C>A p.P382T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54498437; called by muse, mutect2, varscan2
- FOXO4 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as rs1481063814, COSV58576593; called by muse, mutect2, varscan2
- FSTL4 | c.628G>C p.D210H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as COSV54788251; called by muse, mutect2
- GPX5 | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69079973; called by muse, mutect2, varscan2
- HYOU1 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as rs1467335445, COSV68217576; called by muse, mutect2
- IGSF1 | c.3566G>A p.G1189D | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV63838003; called by muse, mutect2
- ITGA10 | c.650G>T p.W217L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV65199588; called by muse, mutect2, varscan2
- KEAP1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50263976, COSV50656013; called by muse, mutect2, varscan2
- KIFAP3 | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV63037921; called by muse, mutect2, varscan2
- KRBOX4 | c.143-1G>T p.X48_splice | Splice Site (SNP) | VAF 21/64 reads (33%) | catalogued as COSV53344485; called by muse, mutect2
- MAP7D3 | c.528C>A p.S176R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV100286149, COSV60172941; called by muse, mutect2, varscan2
- MCF2 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs774395454, COSV58496411; called by muse, mutect2, varscan2
- MDC1 | c.2411G>T p.G804V | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64524818; called by muse, mutect2, varscan2
- MROH6 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV52789426; called by muse, mutect2
- MSANTD3-TMEFF1 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.101); catalogued as COSV58498098; called by muse, mutect2, varscan2
- MTREX | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57930791; called by muse, mutect2
- MYO3A | c.3664G>C p.E1222Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.36); catalogued as COSV56334984, COSV56352401; called by muse, mutect2, varscan2
- MYOC | c.529G>T p.V177L | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV50680415; called by muse, mutect2
- NOL12 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV63031914; called by muse, mutect2
- OR11H12 | c.581G>T p.C194F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101612540; called by mutect2, varscan2
- OR4C16 | c.269T>A p.I90N | Missense Mutation (SNP) | VAF 77/191 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1443214880, COSV58944658; called by muse, mutect2, varscan2
- OR52J3 | c.423A>T p.Q141H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV66747908; called by muse, mutect2, varscan2
- OTOF | c.1517A>G p.N506S | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV55523045; called by muse, mutect2, varscan2
- PARD3B | c.2557G>A p.E853K (on ENST00000406610 / NM_001302769.2; = p.E784K on NM_057177.7) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.98); catalogued as COSV62509163; called by muse, mutect2, varscan2
- PDE2A | c.1950C>A p.Y650* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as COSV100558489; called by muse, mutect2, varscan2
- PIK3CA | c.886C>G p.Q296E | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.049); catalogued as COSV56012741; called by muse, mutect2, varscan2
- PITPNC1 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs753379672, COSV55447062; called by muse, mutect2, varscan2
- PKD2L2 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51794537; called by muse, mutect2, varscan2
- PLPPR4 | c.2058G>T p.K686N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100926965, COSV64565403; called by mutect2, varscan2
- PNPLA4 | c.581A>T p.D194V | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV66854602; called by muse, mutect2, varscan2
- PNPLA6 | c.1811T>G p.F604C (on ENST00000414982 / NM_001166111.2; = p.F556C on NM_006702.5) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV55386475; called by muse, mutect2
- PPARGC1B | c.1951G>T p.A651S | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58533877; called by muse, mutect2
- PPP1R15A | c.1979C>T p.S660F | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.078); catalogued as COSV52340428; called by muse, mutect2
- PSMA4 | c.235A>T p.I79L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.337); catalogued as COSV50385393; called by muse, mutect2, varscan2
- PSMF1 | c.321C>G p.N107K | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.072); catalogued as COSV55676492; called by muse, mutect2, varscan2
- RAB35 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0.403); catalogued as rs781362390, COSV57568734; called by muse, mutect2, varscan2
- RP1L1 | c.5497G>A p.E1833K | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs1443701668, COSV66761230; called by muse, mutect2
- SDHAF2 | c.335C>G p.P112R | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57100366; called by muse, mutect2, varscan2
- SDK1 | c.3904G>A p.E1302K | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.577); catalogued as COSV67376382; called by muse, mutect2, varscan2
- SLC39A8 | c.553-2A>T p.X185_splice | Splice Site (SNP) | VAF 3/25 reads (12%) | catalogued as COSV63224591; called by muse, mutect2
- SLC40A1 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as COSV53725309, COSV99656530; called by muse, mutect2, varscan2
- SLC9A5 | c.1190T>C p.I397T | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55365501; called by muse, mutect2
- SPINT2 | c.173T>C p.V58A | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as COSV56649298; called by muse, mutect2
- STOML3 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.145); catalogued as COSV65512151; called by muse, mutect2, varscan2
- TAF4 | c.1453C>G p.Q485E | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV53344072; called by muse, mutect2, varscan2
- TAPBP | c.725A>G p.D242G | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV70457909; called by muse, mutect2, varscan2
- TBX15 | c.965G>T p.W322L (on ENST00000369429 / NM_001330677.2; = p.W216L on NM_152380.3) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52877296; called by muse, mutect2, varscan2
- TCERG1L | c.539A>T p.E180V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV64059004; called by muse, mutect2, varscan2
- TLE1 | c.347T>A p.M116K | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV64686942; called by muse, mutect2, varscan2
- ULBP2 | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV66266116; called by muse, mutect2, varscan2
- VPS13D | c.9184A>G p.M3062V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs372381323; called by muse, mutect2, varscan2
- VWA2 | c.418A>T p.R140* | Nonsense Mutation (SNP) | VAF 19/96 reads (20%) | catalogued as COSV53912096; called by muse, mutect2, varscan2
- WNT7B | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.17); catalogued as COSV59752670; called by muse, mutect2, varscan2
- ZBTB49 | c.1568T>G p.V523G | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV61926350; called by muse, mutect2, varscan2
- ZBTB9 | c.586G>C p.V196L | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV67702465; called by muse, mutect2
- ZC3H12B | c.1358T>C p.I453T | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV59047483; called by muse, mutect2, varscan2
- ZNF268 | c.731T>C p.I244T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1423356771, COSV57214648; called by muse, mutect2, varscan2
- ACKR2 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- ARHGAP35 | c.4291_4293del p.Q1431del | In Frame Del (DEL) | VAF 37/150 reads (25%) | called by pindel, varscan2
- BTG1 | c.331_337del p.V111Tfs*31 | Frame Shift Del (DEL) | VAF 21/83 reads (25%) | called by mutect2, pindel, varscan2
- CBL | c.1285_1296del p.I429_D432del | In Frame Del (DEL) | VAF 24/93 reads (26%) | called by mutect2, pindel, varscan2
- DZIP3 | c.1850del p.E617Gfs*4 | Frame Shift Del (DEL) | VAF 9/74 reads (12%) | called by mutect2, pindel, varscan2
- RC3H2 | c.2283_2283+5del p.X761_splice | Splice Site (DEL) | VAF 6/57 reads (11%) | called by mutect2, pindel
- SNX19 | c.1548del p.F516Lfs*6 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel, varscan2
- STK11 | c.122_128del p.K41Tfs*8 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel, varscan2
- TRBV20-1 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, varscan2
- ASAP1 | c.378G>A p.K126= | Silent (SNP) | VAF 19/239 reads (8%) | catalogued as COSV63055277; called by muse, mutect2
- ASH2L | c.1713C>T p.S571= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV51702164; called by muse, mutect2, varscan2
- CFAP221 | c.1899C>A p.G633= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV54664046; called by muse, mutect2, varscan2
- CHD7 | c.3951C>T p.R1317= | Silent (SNP) | VAF 10/180 reads (6%) | catalogued as COSV71115267; called by muse, mutect2
- CRYBG2 | c.4806C>T p.A1602= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs915793747, COSV57490967; called by muse, mutect2, varscan2
- GANAB | c.2649T>C p.F883= | Silent (SNP) | VAF 16/244 reads (7%) | catalogued as COSV55490809; called by muse, mutect2
- HSPA2 | c.585G>A p.E195= | Silent (SNP) | VAF 13/161 reads (8%) | catalogued as COSV55971530; called by muse, mutect2
- KLHL4 | c.1692T>A p.G564= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV64148754; called by muse, mutect2
- MYO10 | c.4947C>G p.L1649= | Silent (SNP) | VAF 10/193 reads (5%) | catalogued as COSV57031075; called by muse, mutect2
- NCOA3 | c.1323A>G p.S441= | Silent (SNP) | VAF 16/233 reads (7%) | catalogued as COSV59074225; called by muse, mutect2
- NDUFB2 | c.54C>T p.F18= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV50783968; called by muse, mutect2
- NLE1 | c.201T>G p.A67= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV62605321; called by muse, mutect2
- NOTCH4 | c.4131C>T p.L1377= | Silent (SNP) | VAF 6/81 reads (7%) | catalogued as COSV66684486; called by muse, mutect2
- OR52K2 | c.43T>C p.L15= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV57835941; called by muse, varscan2
- PLEKHS1 | c.711A>C p.P237= (on ENST00000369310 / NM_182601.1; = p.P243= on NM_024889.5) | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV63057103; called by muse, mutect2
- RTL9 | c.1008A>G p.L336= | Silent (SNP) | VAF 32/438 reads (7%) | catalogued as COSV71826585, COSV71826792; called by muse, mutect2
- SAMD10 | c.441C>T p.I147= | Silent (SNP) | VAF 42/165 reads (25%) | catalogued as rs1291635385, COSV53879857; called by muse, mutect2, varscan2
- SP2 | c.747G>A p.K249= | Silent (SNP) | VAF 13/161 reads (8%) | catalogued as COSV65063345; called by muse, mutect2
- SPATA20 | c.855A>G p.R285= (on ENST00000356488 / NM_001258372.1; = p.R301= on NM_022827.4) | Silent (SNP) | VAF 30/400 reads (8%) | catalogued as COSV50070986; called by muse, mutect2
- SRCAP | c.5679G>T p.R1893= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV52682445; called by muse, mutect2, varscan2
- TBC1D24 | c.1155G>A p.Q385= (on ENST00000646147 / NM_001199107.2; = p.Q379= on NM_020705.3) | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV53549148; called by muse, mutect2
- VAT1 | c.622C>T p.L208= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV55897122; called by muse, mutect2, varscan2
- WSCD1 | c.522C>T p.C174= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV58498976; called by muse, mutect2
